Somatic mutation profile of tumor specimen C3N-00198-02 (aliquot CPT0014040006) from CPTAC case C3N-00198, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 55.6 years (20,306 days).
Specimen C3N-00198-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed64311f-b5f9-4ad5-9632-634582a36427.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00198-31 (Blood Derived Normal), aliquot CPT0015030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f08e3533-2e4e-45f4-bf86-0046a6c01706

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, RNA 2, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 24/297 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AP2A2 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 22/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767193206; called by muse, mutect2
- BRAF | c.1580_1594del p.V527_P532delinsA (on ENST00000288602 / NM_001374244.1; = p.V487_P492delinsA on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 30/314 reads (10%) | catalogued as COSV56194068; called by mutect2, pindel
- CDH9 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.398); catalogued as COSV50483092; called by muse, mutect2
- CSDC2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773404459; called by muse, mutect2
- DAAM2 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995610152; called by muse, mutect2
- FAT4 | c.5243C>T p.T1748M | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202038981, COSV100629122; called by muse, mutect2, varscan2
- HDAC6 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as rs781865210, COSV100491400, COSV61930390; called by muse, mutect2
- ING1 | c.910A>T p.N304Y | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs772040695; called by muse, mutect2, varscan2
- NCKAP5 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs112873686; called by muse, mutect2
- NUDT16L1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.257); catalogued as rs1022171006; called by muse, mutect2
- PAMR1 | c.1261C>T p.R421C (on ENST00000619888 / NM_001001991.3; = p.R438C on NM_015430.4) | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs182409377, COSV53509740; called by muse, mutect2
- PCDH11X | c.3166C>A p.H1056N | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV53510400; called by muse, mutect2, varscan2
- PCDHA3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.435); catalogued as COSV100793689; called by muse, mutect2
- POM121L12 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.664); catalogued as rs780329329, COSV68692936; called by muse, mutect2
- SLC8A3 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs766322163, COSV63526605; called by muse, mutect2
- ADAM19 | c.2114C>G p.A705G | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.475); called by muse, mutect2
- ARL6IP6 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDKN2A | c.233_234del p.L78Hfs*41 | Frame Shift Del (DEL) | VAF 55/488 reads (11%) | called by pindel, varscan2
- EPHB6 | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2
- FHL2 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- IGFLR1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- KRT85 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- NDUFA10 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 31/385 reads (8%) | called by muse, mutect2
- SLC25A5 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SPTLC3 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUSD5 | c.586_598+1del p.X196_splice | Splice Site (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel
- AP2A2 | c.1365C>T p.Y455= | Silent (SNP) | VAF 19/537 reads (4%) | catalogued as rs200593003; called by muse, mutect2
- BAG5 | c.303C>G p.A101= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- CELSR1 | c.2223C>T p.G741= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as rs1370896069; called by muse, mutect2
- CHST6 | c.705C>T p.A235= | Silent (SNP) | VAF 36/413 reads (9%) | catalogued as rs1355296973, COSV100178368; called by muse, mutect2
- HCN4 | c.2832G>A p.A944= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs747946171, COSV99984244; called by muse, mutect2, varscan2
- SLC2A9 | c.180C>T p.S60= | Silent (SNP) | VAF 14/332 reads (4%) | catalogued as rs1386419478; called by muse, mutect2
- USP54 | c.297C>T p.L99= | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- C5orf17 | n.214G>A | RNA (SNP) | VAF 7/79 reads (9%) | catalogued as rs1207548427; called by muse, mutect2
- RIN3 | c.44+1347G>A | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as rs866977326; called by muse, mutect2
- SPATA31C1 | n.2798C>T | RNA (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
